Somatic mutation profile of tumor specimen TCGA-BF-AAP1-01A (aliquot TCGA-BF-AAP1-01A-11D-A397-08) from TCGA case TCGA-BF-AAP1, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Epithelioid cell melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 86.7 years (31,666 days).
Specimen TCGA-BF-AAP1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db0d5c7d-f589-4237-9fc2-0066ab22ba79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BF-AAP1-10A (Blood Derived Normal), aliquot TCGA-BF-AAP1-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/373a31f6-4c4b-4ff0-b55e-527d78cf1885

The open-access MAF lists 1,051 somatic variants for this specimen: 653 protein-altering or splice-affecting, 373 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 602, Silent 373, Nonsense Mutation 34, Intron 11, RNA 10, Splice Site 6, Splice Region 6, Frame Shift Del 4, 3'UTR 2, 5'UTR 1, Frame Shift Ins 1, 3'Flank 1.

Variants (750 of 1,051; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 22/56 reads (39%) | hotspot (GDC flag); catalogued as rs121913331, CM920048, COSV57321465, COSV57335215, COSV57385441; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1921A>G p.K641E (on ENST00000288602 / NM_001374244.1; = p.K601E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 85/164 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as rs121913364, CM092083, COSV56058494; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KIF1A | c.2606G>A p.R869H | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs201742042, COSV100240555; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- MAP2K1 | c.364A>G p.N122D | Missense Mutation (SNP) | VAF 37/80 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.665); catalogued as rs876657651, COSV61073416; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- PAK5 | c.519G>A p.M173I | Missense Mutation (SNP) | VAF 95/170 reads (56%) | hotspot (GDC flag); SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs769939031, COSV62021293; called by muse, mutect2, varscan2
- PCSK5 | c.2772G>A p.W924* | Nonsense Mutation (SNP) | VAF 42/75 reads (56%) | hotspot (GDC flag); catalogued as rs1170804599, COSV70449546; called by muse, mutect2, varscan2
- RAC1 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 171/388 reads (44%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as rs1057519874, COSV61821563, COSV61823187; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.1890G>A p.T630= | Splice Region (SNP) | VAF 11/30 reads (37%) | catalogued as rs1204915217, CS100769, COSV100347734, COSV100349983; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as rs1020990116, COSV100750695; called by muse, mutect2, varscan2
- AC109583.1 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.792); catalogued as rs897508638, COSV100167853; called by muse, mutect2, varscan2
- ACSM1 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 69/126 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99532834; called by muse, mutect2, varscan2
- ACSM2B | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 120/290 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61657522; called by muse, varscan2
- ADAD2 | c.1273C>T p.L425F (on ENST00000315906 / NM_001145400.2; = p.L507F on NM_139174.4) | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.45); catalogued as rs1310108989, COSV99235246; called by muse, varscan2
- ADAM12 | c.1870G>A p.D624N | Missense Mutation (SNP) | VAF 95/118 reads (81%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs572965756, COSV100900300; called by muse, mutect2, varscan2
- ADAM18 | c.1761G>A p.M587I | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV55844347; called by muse, mutect2, varscan2
- ADAM20 | c.2102C>T p.P701L | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV99833399; called by muse, mutect2, varscan2
- ADAM30 | c.1832C>T p.S611F | Missense Mutation (SNP) | VAF 44/482 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs143750780; called by muse, mutect2
- ADAMTS15 | c.2390C>T p.S797F | Missense Mutation (SNP) | VAF 49/66 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs1565399715, COSV100143293; called by muse, mutect2, varscan2
- ADAMTSL3 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1173035594, COSV99718210; called by muse, mutect2, varscan2
- ADCY1 | c.980T>A p.L327H | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV99811810; called by muse, mutect2, varscan2
- ADGRB3 | c.3589C>T p.R1197* | Nonsense Mutation (SNP) | VAF 68/85 reads (80%) | catalogued as rs753963400, COSV53235554, COSV53239603; called by muse, mutect2, varscan2
- ADGRF4 | c.1076G>A p.W359* | Nonsense Mutation (SNP) | VAF 21/99 reads (21%) | catalogued as COSV99348265; called by muse, mutect2, varscan2
- ADGRF5 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 77/115 reads (67%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as COSV104368461, COSV99345411; called by muse, mutect2, varscan2
- ADGRV1 | c.6574G>A p.D2192N | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101315773, COSV67994341; called by muse, mutect2, varscan2
- AGBL1 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs1195765001, COSV101222744; called by muse, mutect2, varscan2
- AGXT2 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV51484632; called by muse, mutect2, varscan2
- AHNAK | c.6554C>T p.S2185F | Missense Mutation (SNP) | VAF 128/247 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99946938; called by muse, mutect2, varscan2
- AKAP6 | c.2959G>A p.D987N | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763787749, COSV55203589; called by muse, mutect2, varscan2
- AKR1D1 | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as rs745705949, COSV54337571, COSV54342102; called by muse, varscan2
- AL121899.2 | c.1183C>T p.R395* | Nonsense Mutation (SNP) | VAF 31/92 reads (34%) | catalogued as rs754241815, COSV67351386; called by muse, mutect2, varscan2
- ALLC | c.514G>A p.G172S | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99377756; called by muse, mutect2, varscan2
- ALMS1 | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as rs867586310, COSV52505548; called by muse, mutect2, varscan2
- ALOX15B | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101205602; called by muse, mutect2, varscan2
- AMBN | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.572); catalogued as rs1271205016, COSV59825461; called by muse, mutect2, varscan2
- ANGPTL4 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.166); catalogued as rs1355125510, COSV56845850; called by muse, mutect2, varscan2
- ANKEF1 | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.075); catalogued as rs199561328, COSV101001010; called by muse, mutect2, varscan2
- ANKH | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99414879; called by muse, mutect2, varscan2
- ANKRD30A | c.1078G>A p.E360K (on ENST00000611781; = p.E304K on NM_052997.2) | Missense Mutation (SNP) | VAF 30/35 reads (86%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs77379875; called by mutect2, varscan2
- ANKRD35 | c.2539C>T p.Q847* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | catalogued as COSV100841697; called by muse, mutect2, varscan2
- ANO1 | c.488A>G p.N163S | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs1411999347, COSV100303919; called by muse, mutect2, varscan2
- AOX1 | c.1996G>A p.D666N | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV65979784; called by muse, mutect2, varscan2
- APC | c.6757C>T p.L2253F | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs786203252, COSV57342027, COSV99967229; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARID1A | c.6229C>T p.P2077S | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.084); catalogued as COSV100251252; called by muse, mutect2, varscan2
- ARL6IP1 | c.526C>T p.Q176* | Nonsense Mutation (SNP) | VAF 24/59 reads (41%) | catalogued as COSV100435842; called by muse, mutect2, varscan2
- ARL8A | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99693249; called by muse, mutect2, varscan2
- ARMC3 | c.916C>T p.P306S | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs761740326, COSV99957854; called by muse, mutect2, varscan2
- ASXL3 | c.3160C>T p.L1054F | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99324477; called by muse, mutect2, varscan2
- ATG2B | c.1855C>T p.H619Y | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.057); catalogued as COSV100737927; called by muse, mutect2, varscan2
- ATG7 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762401984, COSV100607143; called by muse, mutect2
- ATP1B4 | c.859G>A p.E287K (on ENST00000218008 / NM_001142447.3; = p.E283K on NM_012069.5) | Missense Mutation (SNP) | VAF 83/91 reads (91%) | SIFT tolerated (0.84); PolyPhen benign (0.284); catalogued as COSV99486278; called by muse, mutect2, varscan2
- ATP4A | c.2378A>T p.K793M | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99382455; called by muse, mutect2, varscan2
- B4GALNT2 | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as COSV100302527; called by muse, mutect2, varscan2
- BCAS3 | c.1492C>G p.L498V | Missense Mutation (SNP) | VAF 60/129 reads (47%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.931); catalogued as COSV66771477; called by muse, mutect2, varscan2
- BICD1 | c.1804C>T p.P602S | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.974); catalogued as COSV99862285; called by muse, mutect2, varscan2
- BMP5 | c.1231C>T p.P411S | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63701190; called by muse, mutect2, varscan2
- BRDT | c.1576C>T p.P526S | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1482718432, COSV100746293; called by muse, mutect2, varscan2
- BRINP2 | c.1793C>T p.S598F | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100838031, COSV64176850; called by mutect2, varscan2
- BTN3A2 | c.980C>T p.S327L | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.054); catalogued as rs542217150, COSV62686896; called by muse, mutect2, varscan2
- C1GALT1 | c.920C>T p.S307F | Missense Mutation (SNP) | VAF 145/380 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56179084; called by muse, mutect2, varscan2
- C6orf15 | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.025); catalogued as COSV99456658; called by muse, mutect2, varscan2
- CA1 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.465); catalogued as rs751837540, COSV99810115; called by muse, mutect2, varscan2
- CA1 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 89/153 reads (58%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV56278260; called by muse, mutect2, varscan2
- CABIN1 | c.6433C>T p.P2145S | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99573073; called by muse, mutect2, varscan2
- CACNA1D | c.2951G>A p.R984K (on ENST00000350061 / NM_001128840.3; = p.R1004K on NM_000720.4) | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99857669; called by muse, mutect2, varscan2
- CACNA1E | c.1862G>A p.G621E | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100702101, COSV62382609; called by muse, mutect2, varscan2
- CACNA1E | c.2243G>A p.R748K | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs769793976, COSV100702102, COSV100705465; called by muse, mutect2, varscan2
- CACNA1S | c.3168G>A p.M1056I | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62941731; called by muse, mutect2, varscan2
- CACNA1S | c.856T>C p.Y286H | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100754916; called by muse, mutect2, varscan2
- CACNA2D3 | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 66/152 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs913543794, COSV99872457; called by muse, mutect2, varscan2
- CADM2 | c.401C>T p.S134L (on ENST00000407528 / NM_001167674.2; = p.S136L on NM_153184.4) | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.348); catalogued as COSV101054390; called by muse, mutect2, varscan2
- CAND2 | c.2906C>T p.S969L (on ENST00000456430 / NM_001162499.2; = p.S876L on NM_012298.3) | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as rs758811542, COSV99928968; called by muse, mutect2, varscan2
- CAPN3 | c.2184G>A p.Q728= | Splice Region (SNP) | VAF 21/62 reads (34%) | catalogued as rs886043220, CS053451, COSV99782459; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAPN6 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); catalogued as COSV100136826; called by muse, mutect2, varscan2
- CARD6 | c.3016C>T p.Q1006* | Nonsense Mutation (SNP) | VAF 83/211 reads (39%) | catalogued as COSV99620660; called by muse, mutect2, varscan2
- CASP2 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 77/268 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100130964; called by muse, mutect2, varscan2
- CATSPERB | c.2792C>T p.A931V | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.747); catalogued as rs762598233, COSV99831144; called by muse, mutect2, varscan2
- CATSPERB | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs1424459391, COSV99831146; called by muse, mutect2, varscan2
- CBARP | c.836C>T p.A279V (on ENST00000382477; = p.A259V on NM_152769.3) | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs1198977923, COSV99289517; called by muse, mutect2
- CBLN2 | c.576G>A p.M192I | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV99504321; called by muse, mutect2, varscan2
- CBLN4 | c.188C>T p.S63L | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.331); catalogued as COSV50352028, COSV50353254; called by muse, mutect2, varscan2
- CCDC102B | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.61); catalogued as COSV60154758; called by muse, mutect2, varscan2
- CCDC114 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as rs1284088961, COSV100196624; called by muse, mutect2, varscan2
- CCDC141 | c.2434G>A p.E812K | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.382); catalogued as COSV99836626; called by muse, mutect2, varscan2
- CCDC144A | c.784G>C p.D262H | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV100138503; called by muse, mutect2, varscan2
- CCDC181 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV100890302; called by muse, mutect2, varscan2
- CCDC86 | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs753482209, COSV57124852; called by muse, mutect2, varscan2
- CD180 | c.1318C>T p.P440S | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99842194; called by muse, mutect2, varscan2
- CD180 | c.348G>A p.M116I | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99842197; called by muse, mutect2, varscan2
- CDC14B | c.550C>T p.H184Y | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1222875456, COSV55791750; called by muse, mutect2, varscan2
- CDH16 | c.1856C>T p.T619I | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as rs760378535, COSV100233807; called by muse, mutect2, varscan2
- CDH2 | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as COSV99296234, COSV99298880; called by muse, mutect2, varscan2
- CDH20 | c.1937G>A p.R646Q | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.605); catalogued as rs762845720, COSV99405068; called by muse, mutect2, varscan2
- CDH9 | c.1981G>A p.D661N | Missense Mutation (SNP) | VAF 62/132 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50250776, COSV50334530; called by muse, mutect2, varscan2
- CDH9 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 71/209 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs776212558, COSV50264628; called by muse, mutect2, varscan2
- CEACAM7 | c.232C>T p.R78* | Nonsense Mutation (SNP) | VAF 75/166 reads (45%) | catalogued as rs782719770, COSV50072867; called by muse, mutect2, varscan2
- CECR2 | c.2788C>T p.P930S (on ENST00000342247 / NM_001290047.2; = p.P747S on NM_001290046.1) | Missense Mutation (SNP) | VAF 59/119 reads (50%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as COSV99377708; called by muse, mutect2, varscan2
- CERS3 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.332); catalogued as COSV52566329, COSV52568330; called by muse, mutect2
- CES3 | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as COSV100309900; called by muse, mutect2, varscan2
- CFAP100 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.884); catalogued as rs200815085, COSV61504003; called by muse, mutect2, varscan2
- CFAP206 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT tolerated (0.1); PolyPhen benign (0.346); catalogued as rs147497097, COSV51534705, COSV99739391; called by muse, mutect2, varscan2
- CFTR | c.1670C>T p.S557F | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CD962512, CM1510239, COSV50044427, COSV99135358; called by muse, mutect2, varscan2
- CHD3 | c.3760C>A p.H1254N | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV57873196; called by muse, mutect2, varscan2
- CLK3 | c.587G>A p.R196Q (on ENST00000395066 / NM_001130028.1; = p.R48Q on NM_003992.4) | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs183588535; called by muse, mutect2, varscan2
- CLRN3 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 46/56 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs754104842, COSV64098240; called by muse, mutect2, varscan2
- CMBL | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.171); catalogued as rs762358334, COSV56983195; called by muse, mutect2, varscan2
- CMYA5 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV101483994, COSV101484208; called by muse, mutect2
- CMYA5 | c.5564C>T p.S1855L | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs762874276, COSV71406857; called by muse, mutect2, varscan2
- CNN1 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as COSV99370630; called by muse, mutect2, varscan2
- CNOT6 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760512456, COSV99993496; called by muse, mutect2, varscan2
- CNTN5 | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.702); catalogued as rs866845091, COSV54279011; called by muse, mutect2, varscan2
- CNTN6 | c.2363C>T p.S788F | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV100610501, COSV63192141; called by muse, mutect2, varscan2
- CNTNAP2 | c.1058G>A p.R353K | Missense Mutation (SNP) | VAF 127/252 reads (50%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.453); catalogued as COSV100665319, COSV62202488; called by muse, mutect2, varscan2
- CNTNAP2 | c.3263G>A p.R1088Q | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as rs201827086, COSV100665321; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL22A1 | c.2119C>T p.P707S | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as COSV100277786; called by muse, mutect2, varscan2
- COL4A5 | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 43/48 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60360895; called by muse, mutect2, varscan2
- CPA2 | c.1240G>A p.V414M | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99743969; called by muse, mutect2, varscan2
- CPNE9 | c.514C>T p.L172F | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99808187; called by muse, mutect2, varscan2
- CREB5 | c.179C>T p.P60L (on ENST00000357727 / NM_182898.4; = p.P53L on NM_004904.3) | Missense Mutation (SNP) | VAF 174/488 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760077074, COSV63220219; called by muse, mutect2, varscan2
- CRHR2 | c.1165C>G p.R389G | Missense Mutation (SNP) | VAF 73/178 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV100529921, COSV59264393, COSV59268177; called by muse, mutect2, varscan2
- CRYBB1 | c.212G>A p.G71D | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99315957; called by muse, mutect2, varscan2
- CRYBB1 | c.211G>A p.G71S | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99315960; called by muse, mutect2, varscan2
- CSNK2A1 | c.1162G>A p.G388S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV99424351; called by muse, mutect2, varscan2
- CYP19A1 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 52/103 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.632); catalogued as rs199887515, COSV99547608; called by muse, mutect2, varscan2
- CYP1B1 | c.1117G>C p.G373R | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.103); catalogued as COSV99307586; called by muse, mutect2, varscan2
- CYP21A2 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 83/241 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.076); catalogued as COSV100925831, COSV100926202; called by muse, mutect2, varscan2
- CYP3A7-CYP3A51P | c.1524G>A p.M508I | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.02); catalogued as rs1407103064; called by muse, mutect2, varscan2
- DAB2 | c.2144C>T p.P715L | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.735); catalogued as COSV100297929; called by muse, mutect2, varscan2
- DBX2 | c.413A>G p.K138R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as COSV100224296; called by muse, mutect2
- DCC | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.593); catalogued as COSV100499370; called by muse, mutect2, varscan2
- DCDC1 | c.2265G>A p.W755* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV100663142; called by muse, mutect2, varscan2
- DDX3X | c.1259G>A p.W420* (on ENST00000399959; = p.W421* on NM_001356.5) | Nonsense Mutation (SNP) | VAF 58/59 reads (98%) | catalogued as COSV101302414; called by muse, mutect2, varscan2
- DEFB113 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as rs1209328851, COSV59038214; called by muse, mutect2, varscan2
- DENND4B | c.2495C>T p.S832F | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV100768590; called by muse, mutect2, varscan2
- DGAT2 | c.962C>T p.S321F | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs1477845039, COSV99929705; called by muse, mutect2, varscan2
- DGKH | c.947C>G p.T316S | Missense Mutation (SNP) | VAF 89/209 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV99818628; called by muse, mutect2, varscan2
- DHDH | c.845G>A p.G282E | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV99668473; called by muse, mutect2, varscan2
- DIDO1 | c.2330C>T p.S777F | Missense Mutation (SNP) | VAF 180/355 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV99825543; called by muse, mutect2, varscan2
- DKK2 | c.706G>A p.G236S | Missense Mutation (SNP) | VAF 58/115 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as COSV99568557; called by muse, mutect2, varscan2
- DMBT1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 72/89 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780912281, COSV57532698; called by muse, mutect2, varscan2
- DMRT3 | c.1276C>T p.P426S | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV51906730; called by muse, mutect2, varscan2
- DMWD | c.641C>T p.T214I | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV99353022; called by muse, mutect2, varscan2
- DMXL2 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.68); PolyPhen benign (0.019); catalogued as COSV51856241; called by muse, mutect2, varscan2
- DNAH10 | c.3830G>A p.G1277E (on ENST00000409039; = p.G1216E on NM_207437.3) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV101292885, COSV68993522; called by muse, mutect2, varscan2
- DNAH10 | c.5127G>A p.M1709I (on ENST00000409039; = p.M1648I on NM_207437.3) | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV68990249, COSV68996365; called by muse, mutect2, varscan2
- DNAH10 | c.11414A>G p.Q3805R (on ENST00000409039; = p.Q3744R on NM_207437.3) | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs767777352, COSV101292181; called by muse, mutect2, varscan2
- DNAH10 | c.11415A>C p.Q3805H (on ENST00000409039; = p.Q3744H on NM_207437.3) | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.05); PolyPhen benign (0.043); catalogued as COSV101292182; called by muse, mutect2, varscan2
- DNAH11 | c.5257G>A p.D1753N | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV100178757, COSV100179159; called by muse, mutect2, varscan2
- DNAH11 | c.7147C>T p.L2383F | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100176762, COSV100178770; called by muse, mutect2, varscan2
- DNAH3 | c.12071G>A p.G4024D | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54504379; called by muse, mutect2, varscan2
- DNAH3 | c.12070G>A p.G4024S | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1567481065, COSV99766640; called by muse, mutect2, varscan2
- DNAH7 | c.9988G>A p.E3330K | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100414812; called by muse, mutect2, varscan2
- DNAH7 | c.9781C>T p.H3261Y | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs1369631290, COSV100414814; called by muse, mutect2, varscan2
- DNAH7 | c.2852G>A p.R951Q | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.805); catalogued as rs763092155, COSV56751432; called by muse, mutect2, varscan2
- DNAJC10 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.255); catalogued as COSV99899138; called by muse, mutect2, varscan2
- DOCK10 | c.4274A>T p.H1425L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV99288980; called by muse, mutect2, varscan2
- DOCK3 | c.1571G>A p.G524D | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99811087; called by muse, mutect2, varscan2
- DOCK6 | c.3557C>T p.P1186L | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99625358; called by muse, mutect2, varscan2
- DPYD | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64594585; called by muse, mutect2, varscan2
- DSCAM | c.4297G>A p.E1433K | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV101259796; called by muse, mutect2, varscan2
- DSCAM | c.2169G>A p.W723* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as rs1292508289, COSV68022924; called by muse, mutect2, varscan2
- DSG1 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.041); catalogued as COSV57134415; called by muse, mutect2, varscan2
- DSG3 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs866204126, COSV57124037; called by muse, mutect2, varscan2
- DYRK4 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.095); catalogued as COSV99156076; called by muse, mutect2, varscan2
- ECE1 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as rs1475764621, COSV99941692; called by muse, mutect2, varscan2
- EEF2KMT | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as rs370055169; called by muse, mutect2, varscan2
- EFHB | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.085); catalogued as rs780719456, COSV55546010; called by muse, mutect2, varscan2
- EHHADH | c.1645C>T p.P549S | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.045); catalogued as COSV99213161; called by muse, mutect2, varscan2
- EMSY | c.3119C>T p.P1040L | Missense Mutation (SNP) | VAF 42/68 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as COSV100595613; called by muse, mutect2, varscan2
- ENPP2 | c.1982C>T p.P661L (on ENST00000075322 / NM_001040092.3; = p.P713L on NM_006209.5) | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.845); catalogued as rs375770524; called by muse, mutect2, varscan2
- EPB41L2 | c.2027C>T p.S676F | Missense Mutation (SNP) | VAF 33/38 reads (87%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV61353102; called by muse, mutect2, varscan2
- EPB42 | c.2053G>A p.V685I (on ENST00000441366 / NM_001114134.2; = p.V715I on NM_000119.3) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.355); catalogued as COSV100281596; called by muse, mutect2, varscan2
- EPHA6 | c.1912G>A p.E638K (on ENST00000389672 / NM_001080448.3; = p.E30K on NM_173655.4) | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.992); catalogued as COSV101061981; called by muse, mutect2, varscan2
- EPHB6 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.48); PolyPhen probably damaging (1); catalogued as rs754050538, COSV67417991; called by muse, mutect2, varscan2
- ERC2 | c.2798G>A p.R933Q | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs776187868, COSV55610156; called by muse, mutect2, varscan2
- ERCC8 | c.36G>T p.L12F | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.152); catalogued as COSV99410320; called by muse, mutect2, varscan2
- ESYT3 | c.370-1G>A p.X124_splice | Splice Site (SNP) | VAF 44/113 reads (39%) | catalogued as COSV100004807; called by muse, mutect2, varscan2
- EYA2 | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100426698; called by muse, mutect2, varscan2
- FADS1 | c.326A>G p.H109R | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV99952172; called by muse, mutect2
- FAH | c.1253C>T p.P418L | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1353084230, COSV99930197; called by muse, mutect2, varscan2
- FAM135B | c.1757G>A p.G586E | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52732083; called by muse, mutect2, varscan2
- FAM160A2 | c.2623C>T p.R875W (on ENST00000449352 / NM_001098794.2; = p.R889W on NM_032127.4) | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759796766, COSV56415146; called by muse, mutect2, varscan2
- FAM172A | c.134A>T p.E45V | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV101232722; called by muse, mutect2, varscan2
- FAM83B | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.223); catalogued as COSV60928578; called by muse, mutect2, varscan2
- FAT1 | c.13552C>T p.P4518S | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.075); catalogued as rs772588307, COSV71673535; called by muse, mutect2, varscan2
- FAT3 | c.10253C>T p.A3418V | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); catalogued as COSV99964851; called by muse, mutect2, varscan2
- FAT3 | c.12649G>A p.D4217N | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.167); catalogued as COSV99964852; called by muse, mutect2, varscan2
- FAT4 | c.13597G>A p.G4533R | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.4); catalogued as rs999854092, COSV58708176; called by muse, mutect2, varscan2
- FCHSD1 | c.1799C>T p.P600L | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99781309; called by muse, mutect2, varscan2
- FCRL5 | c.2824C>T p.P942S | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as COSV100708813; called by muse, mutect2, varscan2
- FER1L6 | c.623G>A p.G208E | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs1477844697, COSV101205754; called by muse, mutect2, varscan2
- FER1L6 | c.5365G>A p.E1789K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs762512675, COSV67550569; called by muse, mutect2, varscan2
- FEZF1 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 83/236 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.156); catalogued as COSV100484479; called by muse, mutect2, varscan2
- FGD3 | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1463216793, COSV61598485; called by muse, mutect2, varscan2
- FHDC1 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.476); catalogued as rs1358542614, COSV99471193; called by muse, varscan2
- FLT3 | c.2323G>A p.E775K | Missense Mutation (SNP) | VAF 46/82 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as COSV54059355; called by muse, mutect2, varscan2
- FREM1 | c.5774G>T p.R1925M | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs1433202258, COSV101084254; called by muse, mutect2, varscan2
- FREM1 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 25/31 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs535449864, COSV66522124; called by muse, mutect2, varscan2
- FRMPD3 | c.1667C>T p.S556F | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV99346133; called by muse, mutect2, varscan2
- FSD2 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); catalogued as COSV58011653; called by muse, mutect2, varscan2
- FTMT | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs865797696, COSV58419985; called by muse, mutect2, varscan2
- FZD2 | c.1103A>G p.N368S | Missense Mutation (SNP) | VAF 49/66 reads (74%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.627); catalogued as COSV100190358; called by muse, mutect2, varscan2
- GABRA3 | c.1376C>T p.S459F | Missense Mutation (SNP) | VAF 56/61 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64795656; called by muse, mutect2, varscan2
- GALNT17 | c.1080+1G>A p.X360_splice | Splice Site (SNP) | VAF 25/93 reads (27%) | catalogued as COSV100353492; called by muse, mutect2, varscan2
- GALNT6 | c.1148A>T p.N383I | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100695405; called by muse, mutect2, varscan2
- GAREM1 | c.2477C>T p.S826F (on ENST00000269209 / NM_001242409.2; = p.S825F on NM_022751.3) | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV99330499; called by muse, mutect2, varscan2
- GDA | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 74/149 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99429110; called by muse, mutect2, varscan2
- GFRAL | c.344G>A p.W115* | Nonsense Mutation (SNP) | VAF 33/182 reads (18%) | catalogued as rs745662274, COSV61231307; called by muse, mutect2, varscan2
- GFRAL | c.616C>T p.H206Y | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100474999; called by muse, mutect2, varscan2
- GIMAP2 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV99785237; called by muse, mutect2, varscan2
- GLRB | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as COSV100029657; called by muse, mutect2, varscan2
- GLYATL1 | c.674C>T p.P225L (on ENST00000317391 / NM_001354699.1; = p.P256L on NM_080661.4) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.928); catalogued as COSV100265279; called by muse, mutect2, varscan2
- GMPS | c.723T>C p.V241= | Splice Region (SNP) | VAF 21/60 reads (35%) | catalogued as COSV99903085; called by muse, mutect2, varscan2
- GNAL | c.1079G>A p.R360H (on ENST00000269162 / NM_001142339.3; = p.R437H on NM_182978.4) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs774941073; called by mutect2, varscan2
- GPR139 | c.377G>A p.R126K | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58502451, COSV58504677; called by muse, mutect2, varscan2
- GPR174 | c.820C>T p.H274Y | Missense Mutation (SNP) | VAF 47/52 reads (90%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52133612, COSV99338087; called by muse, mutect2, varscan2
- GRID1 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 52/62 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199714522; called by muse, mutect2, varscan2
- GRIK5 | c.1269+1G>A p.X423_splice | Splice Site (SNP) | VAF 22/53 reads (42%) | catalogued as COSV53480439, COSV99490402; called by muse, mutect2, varscan2
- GRIN3A | c.2086G>A p.E696K | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868638738, COSV62451702; called by muse, mutect2, varscan2
- GRM4 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs866300355, COSV100946098; called by muse, mutect2, varscan2
- GSS | c.806G>A p.G269D | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99404363; called by muse, mutect2, varscan2
- H2BC6 | c.146T>C p.V49A | Missense Mutation (SNP) | VAF 95/365 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61591627; called by muse, mutect2, varscan2
- HACD2 | c.251T>A p.F84Y | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV101045876; called by muse, mutect2
- HAPLN1 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs115901495, COSV57147386; called by muse, mutect2, varscan2
- HAVCR1 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 156/356 reads (44%) | catalogued as COSV59397432, COSV59401595; called by muse, mutect2, varscan2
- HBG2 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs151258456, COSV57963441; called by muse, mutect2, varscan2
- HCLS1 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs767550556, COSV58857423; called by muse, mutect2, varscan2
- HCN1 | c.2542G>A p.G848R | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57513602; called by muse, mutect2, varscan2
- HECW1 | c.3094G>A p.G1032R | Missense Mutation (SNP) | VAF 90/158 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs373090671, COSV101223939; called by muse, mutect2, varscan2
- HELQ | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99787606; called by muse, mutect2, varscan2
- HK2 | c.1891G>A p.E631K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as rs780187573, COSV99308918; called by muse, mutect2
- HNF4G | c.308C>T p.S103F (on ENST00000354370 / NM_001330561.2; = p.S150F on NM_004133.5) | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as rs1212794253, COSV100584345; called by muse, mutect2, varscan2
- HNF4G | c.548G>A p.G183E (on ENST00000354370 / NM_001330561.2; = p.G230E on NM_004133.5) | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100584346; called by muse, mutect2, varscan2
- HNRNPCL1 | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV100508925; called by muse, mutect2, varscan2
- HOXA3 | c.800G>A p.S267N | Missense Mutation (SNP) | VAF 41/221 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100415415; called by muse, mutect2, varscan2
- HRH3 | c.522G>A p.W174* | Nonsense Mutation (SNP) | VAF 17/51 reads (33%) | catalogued as COSV100420544; called by muse, mutect2, varscan2
- HSD17B3 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 63/147 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV100931253, COSV64558439; called by muse, mutect2, varscan2
- HSPA8 | c.1736A>G p.N579S | Missense Mutation (SNP) | VAF 35/42 reads (83%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs1317857757, COSV99914342; called by muse, mutect2, varscan2
- HTR1E | c.653C>T p.S218L | Missense Mutation (SNP) | VAF 44/56 reads (79%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as COSV100541058; called by muse, mutect2, varscan2
- HTR1E | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 55/69 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs61735411, COSV59507076; called by muse, mutect2, varscan2
- HTR3B | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs1565555702, COSV52742930; called by muse, mutect2, varscan2
- HTR5A | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 81/185 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1359995825, COSV55280803; called by muse, mutect2, varscan2
- HVCN1 | c.659T>G p.V220G | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV54373303; called by muse, mutect2, varscan2
- HYDIN | c.7681G>A p.E2561K | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs541414127, COSV59252991; called by muse, mutect2, varscan2
- IFNAR1 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV99531592; called by muse, mutect2, varscan2
- IGKV2-28 | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.903); catalogued as rs1004302709; called by mutect2, varscan2
- IGSF21 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.368); catalogued as rs183577264, COSV99243806; called by muse, mutect2, varscan2
- IL1RL1 | c.440G>A p.W147* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as rs773936345, COSV99293946; called by muse, mutect2, varscan2
- IL32 | c.442G>A p.E148K (on ENST00000396890 / NM_001308078.4; = p.E102K on NM_004221.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.103); catalogued as rs757665795, COSV99145486; called by muse, mutect2, varscan2
- INMT | c.191C>T p.S64L | Missense Mutation (SNP) | VAF 99/500 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99184995; called by muse, mutect2, varscan2
- ITCH | c.1915C>T p.R639C (on ENST00000262650 / NM_001257137.3; = p.R598C on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/102 reads (63%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.953); catalogued as rs757758667, COSV99391853; called by muse, mutect2, varscan2
- ITGA4 | c.755-1G>A p.X252_splice | Splice Site (SNP) | VAF 14/30 reads (47%) | catalogued as COSV99276121; called by muse, mutect2, varscan2
- ITGAL | c.1832G>A p.S611N | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.173); catalogued as COSV100776211; called by muse, mutect2, varscan2
- ITGB6 | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs540109604, COSV51790483; called by muse, mutect2, varscan2
- ITPRID1 | c.3017C>T p.P1006L | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV100086205; called by muse, mutect2, varscan2
- JMY | c.1527G>A p.E509= | Splice Region (SNP) | VAF 21/45 reads (47%) | catalogued as rs1324876654, COSV101267995; called by muse, mutect2, varscan2
- KCNH5 | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV100526166, COSV59757924; called by muse, mutect2, varscan2
- KCNIP4 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs752727409, COSV54842738; called by muse, mutect2, varscan2
- KCNK1 | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100785685; called by muse, mutect2, varscan2
- KCNK10 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56640100; called by muse, mutect2, varscan2
- KCNS2 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.151); catalogued as rs138992941; called by muse, mutect2, varscan2
- KCNT2 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.312); catalogued as rs1175642611, COSV99653041; called by muse, mutect2, varscan2
- KDM6B | c.1318C>T p.P440S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV54681628; called by muse, mutect2, varscan2
- KDR | c.2639G>A p.R880Q | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs368407075, COSV99817388; called by muse, mutect2, varscan2
- KIAA1109 | c.2980C>T p.R994C | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs371237864; called by muse, mutect2, varscan2
- KIAA1522 | c.413C>T p.S138F (on ENST00000373480 / NM_001198972.2; = p.S197F on NM_020888.3) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99614492; called by muse, mutect2, varscan2
- KIF13A | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99435428, COSV99438328; called by muse, mutect2, varscan2
- KIF2B | c.1564C>T p.P522S | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52133466, COSV52133823; called by muse, mutect2, varscan2
- KLB | c.322T>A p.S108T | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99962082; called by muse, mutect2, varscan2
- KLHL5 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as rs757541285, COSV99785138; called by muse, mutect2, varscan2
- KLK11 | c.169G>A p.G57R (on ENST00000594768 / NM_144947.3; = p.G25R on NM_006853.3) | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1479504720, COSV99141896; called by muse, mutect2, varscan2
- KMT2C | c.4274-1G>A p.X1425_splice | Splice Site (SNP) | VAF 37/164 reads (23%) | catalogued as COSV100070622; called by muse, mutect2, varscan2
- KRT34 | c.608G>A p.S203N | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as rs1375975965, COSV101222601; called by muse, mutect2, varscan2
- KRT6A | c.1258C>T p.L420F | Missense Mutation (SNP) | VAF 50/96 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1256947992, COSV100416903; called by muse, mutect2, varscan2
- KRT6A | c.837G>A p.M279I | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as COSV100416904; called by muse, mutect2, varscan2
- KRT7 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV59333035; called by muse, mutect2, varscan2
- KRT74 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs148260181; called by muse, mutect2, varscan2
- KYNU | c.1328C>T p.S443F | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99933109; called by muse, mutect2, varscan2
- L3HYPDH | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs201296859, COSV99711346; called by muse, mutect2, varscan2
- LAMA1 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.329); catalogued as COSV101055974; called by muse, mutect2, varscan2
- LAMA5 | c.4694C>T p.S1565F | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as rs781125987, COSV99438730; called by muse, mutect2, varscan2
- LAMB2 | c.4502C>T p.S1501F | Missense Mutation (SNP) | VAF 61/120 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV100026070; called by muse, mutect2, varscan2
- LILRA2 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as rs372106807; called by muse, mutect2, varscan2
- LILRB4 | c.1147G>A p.E383K (on ENST00000391733 / NM_001278428.3; = p.E382K on NM_001278426.3) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); catalogued as COSV54404468; called by muse, mutect2, varscan2
- LIPC | c.545G>A p.G182D | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs560972096, COSV100134466; called by muse, mutect2, varscan2
- LMOD1 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs367728915; called by muse, mutect2, varscan2
- LMX1A | c.849G>A p.M283I | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs373067545; called by muse, mutect2, varscan2
- LRCH2 | c.553G>A p.V185I | Missense Mutation (SNP) | VAF 22/25 reads (88%) | SIFT tolerated (1); PolyPhen possibly damaging (0.581); catalogued as COSV100406714; called by muse, mutect2, varscan2
- LRP1B | c.11221G>A p.E3741K | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV101255501, COSV67249308; called by muse, mutect2, varscan2
- LRRC4C | c.1045T>A p.F349I | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as COSV99537842; called by muse, mutect2, varscan2
- LRRC7 | c.399A>T p.K133N (on ENST00000651989 / NM_001370785.2; = p.K100N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV99226043; called by muse, mutect2, varscan2
- LRRC7 | c.3319G>A p.D1107N (on ENST00000651989 / NM_001370785.2; = p.D1074N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99226046; called by muse, mutect2, varscan2
- LRRIQ3 | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.071); catalogued as COSV100598677; called by muse, mutect2, varscan2
- LUZP4 | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 57/71 reads (80%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100904849; called by muse, mutect2, varscan2
- LY75-CD302 | c.5614T>A p.F1872I | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.085); catalogued as COSV99373705; called by muse, mutect2, varscan2
- MACC1 | c.1799G>A p.G600E | Missense Mutation (SNP) | VAF 116/322 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60541369; called by muse, mutect2, varscan2
- MACF1 | c.13654G>A p.E4552K (on ENST00000372915; = p.E2485K on NM_012090.5) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as rs1412716890, COSV99243483; called by muse, mutect2, varscan2
- MAGEC3 | c.1870G>A p.D624N | Missense Mutation (SNP) | VAF 40/48 reads (83%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as COSV100025240; called by muse, mutect2, varscan2
- MAP3K14 | c.2069C>T p.P690L | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs370000467; called by muse, mutect2, varscan2
- MAP3K21 | c.956C>T p.S319F | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64044668; called by muse, mutect2, varscan2
- MAP4 | c.1814C>T p.S605F | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV100805647; called by muse, mutect2, varscan2
- MAP4K1 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV101204194; called by muse, mutect2, varscan2
- MAP4K3 | c.2257C>T p.R753* | Nonsense Mutation (SNP) | VAF 23/42 reads (55%) | catalogued as rs1432706724, COSV55710142; called by muse, mutect2, varscan2
- MAP9 | c.1900C>T p.P634S | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.397); catalogued as COSV60903623; called by muse, mutect2, varscan2
- MAPK3 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV99531489; called by muse, mutect2, varscan2
- MBD2 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.401); catalogued as COSV99840069; called by muse, mutect2, varscan2
- MCTP2 | c.2091T>A p.F697L | Missense Mutation (SNP) | VAF 63/165 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.305); catalogued as COSV100752065; called by muse, mutect2, varscan2
- MEGF11 | c.1573G>A p.D525N | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.881); catalogued as COSV99987480; called by muse, mutect2, varscan2
- MEGF8 | c.4178C>T p.S1393F (on ENST00000251268 / NM_001271938.2; = p.S1326F on NM_001410.3) | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1464353358, COSV99235734; called by muse, mutect2, varscan2
- MEP1B | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as rs758268457, COSV52497956; called by muse, mutect2, varscan2
- MEPE | c.881C>T p.T294I | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100734938; called by muse, mutect2, varscan2
- METTL9 | c.571C>T p.L191F | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100820493, COSV100820543; called by muse, mutect2, varscan2
- MFSD2B | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV100601038; called by muse, mutect2, varscan2
- MGAM | c.1422G>A p.M474I | Missense Mutation (SNP) | VAF 62/157 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV101527451; called by muse, mutect2, varscan2
- MGAM | c.3289C>T p.R1097C | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs749121609, COSV72073544; called by muse, mutect2, varscan2
- MICAL2 | c.3269G>A p.R1090K | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.006); catalogued as COSV99817203; called by muse, mutect2, varscan2
- MIER2 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV53394944; called by muse, mutect2, varscan2
- MKRN3 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); catalogued as rs757586782, COSV58809328, COSV58812406; called by muse, mutect2, varscan2
- MLIP | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV51425831, COSV99229056; called by muse, mutect2, varscan2
- MPO | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 58/113 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); catalogued as COSV99228669; called by muse, mutect2, varscan2
- MRAP2 | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 48/63 reads (76%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1162068455, COSV57633991; called by muse, mutect2, varscan2
- MRO | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 88/202 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.83); catalogued as COSV56497667; called by muse, mutect2, varscan2
- MROH2B | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as rs377405961; called by muse, mutect2, varscan2
- MRPS30 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as rs1452865643, COSV101539270; called by muse, mutect2
- MRPS30 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV101539271; called by muse, mutect2
- MS4A14 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.03); catalogued as COSV100280299, COSV55739222; called by muse, mutect2, varscan2
- MSS51 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as COSV100200138; called by muse, mutect2, varscan2
- MST1 | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV99610716; called by muse, mutect2, varscan2
- MUC16 | c.41222C>T p.A13741V | Missense Mutation (SNP) | VAF 82/164 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.961); catalogued as COSV101109841, COSV66692001; called by muse, mutect2, varscan2
- MUC16 | c.24077C>T p.S8026L | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.133); catalogued as COSV101199493; called by muse, mutect2, varscan2
- MUC16 | c.15125C>T p.S5042F | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.721); catalogued as rs865869833, COSV67477582; called by muse, mutect2, varscan2
- MUC16 | c.8650G>A p.G2884R | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs764839302, COSV101199494; called by muse, mutect2, varscan2
- MUC16 | c.6578C>T p.S2193F | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV67462513; called by muse, mutect2, varscan2
- MUC16 | c.6395C>T p.S2132F | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV101199495; called by muse, mutect2, varscan2
- MUC16 | c.2654G>T p.R885M | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.011); catalogued as COSV101199496; called by muse, mutect2, varscan2
- MUC17 | c.11248G>A p.E3750K | Missense Mutation (SNP) | VAF 91/269 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV100072357, COSV60290926; called by muse, mutect2, varscan2
- MUSK | c.1759G>A p.G587R | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99503988; called by muse, mutect2, varscan2
- MYH15 | c.2983G>A p.E995K | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as COSV99843004; called by muse, mutect2, varscan2
- MYH2 | c.3547G>A p.D1183N | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55443092, COSV99819933; called by muse, mutect2, varscan2
- MYH6 | c.2430G>A p.R810= | Splice Region (SNP) | VAF 17/44 reads (39%) | catalogued as COSV100676467; called by muse, mutect2
- MYO1A | c.520C>A p.L174I | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.253); catalogued as COSV100270847; called by muse, mutect2
- MYO3B | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.53); catalogued as COSV100509938; called by muse, mutect2, varscan2
- MYO5C | c.3955-2A>G p.X1319_splice | Splice Site (SNP) | VAF 12/28 reads (43%) | catalogued as rs1162031289, COSV99954604; called by muse, mutect2, varscan2
- MYOCD | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV58503859; called by muse, mutect2, varscan2
- MYRIP | c.472G>A p.G158R | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100218867; called by muse, mutect2, varscan2
- MYZAP | c.1248G>T p.Q416H (on ENST00000267853 / NM_001018100.5; = p.Q388H on NM_152451.7) | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1237096172, COSV99984864; called by muse, mutect2, varscan2
- NAP1L2 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 26/31 reads (84%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV100999200; called by muse, mutect2, varscan2
- NAV2 | c.7017C>T p.I2339= (on ENST00000396087 / NM_001244963.2; = p.I2280= on NM_145117.5) | Splice Region (SNP) | VAF 20/46 reads (43%) | catalogued as rs763894768, COSV60656191; called by muse, mutect2, varscan2
- NAV3 | c.6876G>A p.W2292* (on ENST00000397909 / NM_001024383.2; = p.W2270* on NM_014903.6) | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as COSV99889582; called by muse, mutect2, varscan2
- NBEA | c.8642G>A p.G2881E | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV59786753; called by muse, mutect2, varscan2
- NCK1 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV99999493; called by muse, mutect2, varscan2
- NCKAP1L | c.3341G>A p.R1114Q | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs867197350, COSV53203951; called by muse, mutect2, varscan2
- NCKAP5 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as COSV58480051; called by muse, mutect2, varscan2
- NCOA3 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 46/89 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs143752906; called by muse, mutect2, varscan2
- NCOA6 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as COSV100749959, COSV100750354; called by muse, mutect2, varscan2
- NDN | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.517); catalogued as rs1413961902, COSV100086404; called by muse, mutect2, varscan2
- NEIL3 | c.995C>A p.P332H | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99220284; called by muse, mutect2, varscan2
- NELL2 | c.2021G>A p.R674Q | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100421185, COSV61569528; called by muse, mutect2, varscan2
- NEXMIF | c.3023C>T p.S1008F | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV99280495; called by muse, mutect2, varscan2
- NFATC3 | c.1705C>T p.R569C | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1202433397, COSV60472272; called by muse, mutect2, varscan2
- NID2 | c.1949G>A p.G650D | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99356339; called by muse, mutect2, varscan2
- NKAIN2 | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 34/45 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs866453470, COSV63644246; called by muse, mutect2, varscan2
- NKAPL | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.442); catalogued as rs775695661, COSV100642490; called by muse, mutect2, varscan2
- NLGN4Y | c.2020G>A p.E674K | Missense Mutation (SNP) | VAF 61/72 reads (85%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs267606534, COSV59296835; called by muse, mutect2, varscan2
- NLN | c.1989G>A p.M663I | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.215); catalogued as COSV101114220; called by muse, mutect2, varscan2
- NLRP13 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV61623768; called by muse, mutect2, varscan2
- NME8 | c.259C>T p.L87F | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99553153; called by muse, mutect2, varscan2
- NME8 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 76/185 reads (41%) | SIFT tolerated (0.72); PolyPhen benign (0.019); catalogued as rs866091840, COSV52256599; called by muse, mutect2, varscan2
- NME8 | c.1435G>A p.D479N | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV99553156; called by muse, mutect2, varscan2
- NMUR2 | c.788G>A p.R263K | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.11); catalogued as COSV54917457; called by muse, mutect2, varscan2
- NOP53 | c.749C>T p.S250F | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.25); catalogued as rs900359255, COSV99884283; called by muse, mutect2, varscan2
- NOS1 | c.710G>A p.G237E | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV57613128; called by muse, mutect2, varscan2
- NOTCH4 | c.2902G>A p.E968K | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV100900615; called by muse, mutect2, varscan2
- NPIPB15 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 55/320 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (1); catalogued as COSV101465980; called by muse, mutect2, varscan2
- NPTX2 | c.1241G>A p.G414E | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1340512901, COSV99674620, COSV99674833; called by muse, mutect2, varscan2
- NRCAM | c.236C>T p.S79F (on ENST00000379028 / NM_001371124.1; = p.S73F on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1372452559, COSV100694575; called by muse, mutect2, varscan2
- NRG3 | c.1372C>A p.P458T | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV100931210, COSV64579007; called by muse, mutect2, varscan2
- NUDT14 | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1174208316, COSV100078191; called by muse, mutect2, varscan2
- NUMBL | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99424876; called by muse, mutect2
- NUP210L | c.2918C>T p.P973L | Missense Mutation (SNP) | VAF 61/97 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99667779; called by muse, mutect2, varscan2
- OGDH | c.2173G>A p.V725M | Missense Mutation (SNP) | VAF 54/101 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99758671; called by muse, mutect2, varscan2
- OLFML2B | c.1217G>A p.R406K | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV99668324; called by muse, mutect2, varscan2
- OR11H1 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV99421539; called by mutect2, varscan2
- OR11H1 | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.43); catalogued as COSV99421738; called by muse, mutect2, varscan2
- OR11H12 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 64/161 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs1370242111, COSV73569293; called by muse, mutect2, varscan2
- OR13C2 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV101604863; called by muse, mutect2, varscan2
- OR2A12 | c.926C>T p.S309L | Missense Mutation (SNP) | VAF 118/304 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs769397640, COSV68821096; called by muse, mutect2, varscan2
- OR2A14 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 86/412 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.023); catalogued as COSV68718230; called by muse, varscan2
- OR4A5 | c.160G>A p.G54S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.033); catalogued as COSV100157042, COSV60525244; called by muse, mutect2, varscan2
- OR51B4 | c.785G>A p.G262E | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs1185729619, COSV100971158, COSV66517532; called by muse, mutect2, varscan2
- OR51M1 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 52/91 reads (57%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs1010504878, COSV60783841; called by muse, mutect2, varscan2
- OR56A4 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as rs761678088, COSV100417540; called by muse, mutect2, varscan2
- OR5AK2 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58805382; called by muse, mutect2, varscan2
- OR5D13 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1317455066, COSV100686829; called by muse, mutect2, varscan2
- OR5D18 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 92/191 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as COSV61736907; called by muse, mutect2, varscan2
- OR5K1 | c.684G>A p.M228I | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.85); catalogued as rs867447128, COSV60303853; called by muse, mutect2, varscan2
- OR5T2 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs774915672, COSV57587806; called by muse, mutect2, varscan2
- OR8B2 | c.929G>A p.R310K | Missense Mutation (SNP) | VAF 29/34 reads (85%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV66664137; called by muse, mutect2, varscan2
- OR8B8 | c.404C>T p.T135I | Missense Mutation (SNP) | VAF 21/22 reads (95%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as rs764848219, COSV100044997; called by muse, mutect2, varscan2
- ORC1 | c.1713G>A p.M571I | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100856648; called by muse, mutect2, varscan2
- OSMR | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV99953030; called by muse, mutect2, varscan2
- OTOL1 | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60006253; called by muse, mutect2, varscan2
- OTUD7A | c.1358C>T p.P453L (on ENST00000307050 / NM_001382637.1; = p.P446L on NM_130901.3) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1428104635, COSV100192317; called by muse, mutect2, varscan2
- PAGE1 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 34/38 reads (89%) | SIFT tolerated (0.15); PolyPhen benign (0.105); catalogued as rs782482756, COSV65998898; called by muse, mutect2, varscan2
- PAPPA2 | c.2515G>A p.E839K | Missense Mutation (SNP) | VAF 73/176 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV62773994, COSV62777102; called by muse, mutect2, varscan2
- PAPPA2 | c.3166C>T p.L1056F | Missense Mutation (SNP) | VAF 81/157 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.288); catalogued as COSV62795264; called by muse, mutect2, varscan2
- PAX6 | c.328G>A p.G110R | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as COSV53795657, COSV99570304; called by muse, mutect2, varscan2
- PBX1 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.836); catalogued as rs868781414, COSV63348662; called by muse, mutect2, varscan2
- PCDHA10 | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 83/182 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.146); catalogued as rs782392001, COSV100249816; called by muse, mutect2, varscan2
- PCDHA2 | c.917G>A p.G306E | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.517); catalogued as rs782787763, COSV65365287; called by muse, mutect2, varscan2
- PCDHB3 | c.1106G>A p.S369N | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.114); catalogued as COSV99164939; called by muse, mutect2, varscan2
- PCDHB6 | c.2026C>T p.P676S | Missense Mutation (SNP) | VAF 63/139 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.079); catalogued as COSV99170070; called by muse, mutect2, varscan2
- PCDHB7 | c.2164C>T p.R722C | Missense Mutation (SNP) | VAF 61/268 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.556); catalogued as rs1554280422, COSV50753646; called by muse, mutect2, varscan2
- PCDHGA4 | c.368G>A p.R123K | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs1359240503, COSV99536036; called by muse, mutect2, varscan2
- PCDHGA6 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99536040; called by muse, mutect2, varscan2
- PCDHGB2 | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99536038; called by muse, mutect2, varscan2
- PCK1 | c.888G>A p.M296I | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.175); catalogued as COSV100100381; called by muse, mutect2, varscan2
- PCLO | c.14945G>A p.G4982E | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.387); catalogued as COSV61618236; called by muse, mutect2, varscan2
- PDE1C | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100372169; called by muse, mutect2, varscan2
- PDE1C | c.487T>A p.L163I | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as COSV100372171; called by muse, mutect2, varscan2
- PDE1C | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 115/286 reads (40%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.7); catalogued as rs866066614, COSV68810509; called by muse, mutect2, varscan2
- PDE7B | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 54/64 reads (84%) | catalogued as COSV57502830; called by muse, mutect2, varscan2
- PDE7B | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 58/64 reads (91%) | SIFT tolerated (0.15); PolyPhen benign (0.153); catalogued as COSV100367626; called by muse, mutect2, varscan2
- PDPK1 | c.115C>G p.P39A | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.022); catalogued as rs1245860798; called by mutect2, varscan2
- PGLYRP2 | c.584G>A p.G195D | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.1); catalogued as COSV99483943; called by muse, mutect2, varscan2
- PHF2 | c.2399C>T p.S800F | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV63678300, COSV63682040; called by muse, mutect2, varscan2
- PIK3C2A | c.4847G>A p.R1616Q | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99790569; called by muse, mutect2, varscan2
- PIWIL3 | c.1468G>A p.G490R | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV100177550; called by muse, mutect2, varscan2
- PKHD1L1 | c.7844C>T p.T2615I | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs148709032, COSV101005975; called by muse, mutect2, varscan2
- PLA2G4A | c.924G>A p.M308I | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.542); catalogued as COSV100820502; called by muse, mutect2, varscan2
- PLA2G6 | c.620G>A p.R207K | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100140348; called by muse, mutect2, varscan2
- PLCE1 | c.1582C>T p.L528F | Missense Mutation (SNP) | VAF 35/45 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99594555; called by muse, mutect2, varscan2
- PLCL2 | c.1940C>T p.S647F (on ENST00000615277 / NM_001144382.2; = p.S521F on NM_015184.5) | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67621175; called by muse, mutect2, varscan2
- PLCL2 | c.3355G>A p.E1119K (on ENST00000615277 / NM_001144382.2; = p.E993K on NM_015184.5) | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.864); catalogued as rs1559295100, COSV69057054; called by muse, mutect2, varscan2
- PLEKHA7 | c.2894G>A p.R965Q | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs977327408, COSV60580352; called by muse, mutect2, varscan2
- PLEKHG4B | c.2330dup p.V778Gfs*17 (on ENST00000283426; = p.V1134Gfs*17 on NM_052909.5) | Frame Shift Ins (INS) | VAF 8/32 reads (25%) | catalogued as rs746346365; called by mutect2, pindel, varscan2
- PLK3 | c.1550C>T p.S517F | Missense Mutation (SNP) | VAF 93/163 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as COSV100221117; called by muse, mutect2, varscan2
- PNLIP | c.1133G>A p.G378E | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100981768; called by muse, mutect2, varscan2
- POLE | c.5755C>T p.P1919S | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.67); PolyPhen benign (0.065); catalogued as COSV100266105; called by muse, mutect2, varscan2
- POM121L12 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.047); catalogued as rs1411868620, COSV101374902, COSV68692602; called by muse, mutect2, varscan2
- POMGNT2 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 59/112 reads (53%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV100768030; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.406G>T p.A136S | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV99461173; called by muse, mutect2, varscan2
- PPARGC1A | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as rs368992605; called by muse, mutect2, varscan2
- PPP1R13B | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99158467; called by muse, mutect2, varscan2
- PPP1R16B | c.817G>A p.G273R | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1417224685, COSV100239282; called by muse, mutect2, varscan2
- PPP1R3A | c.1457G>A p.R486Q | Missense Mutation (SNP) | VAF 69/207 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as rs756250126, COSV52878213, COSV52879159, COSV99493264; called by muse, mutect2, varscan2
- PPP6C | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV101001130; called by muse, mutect2, varscan2
- PRAMEF19 | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 153/296 reads (52%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.663); catalogued as rs1392774031; called by muse, mutect2, varscan2
- PRDM2 | c.4303C>T p.Q1435* | Nonsense Mutation (SNP) | VAF 50/180 reads (28%) | catalogued as COSV99341413; called by muse, mutect2, varscan2
- PRKAA2 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 142/289 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as rs141766544, COSV64801669; called by muse, mutect2, varscan2
- PRKG2 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 138/369 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.065); catalogued as rs867660938, COSV52320273; called by muse, mutect2, varscan2
- PROS1 | c.1787C>A p.S596Y | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV101260396; called by muse, mutect2, varscan2
- PROX1 | c.2137G>T p.V713F | Missense Mutation (SNP) | VAF 58/103 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99799130; called by muse, mutect2, varscan2
- PRPF38B | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.029); catalogued as COSV100898252; called by muse, varscan2
- PRUNE2 | c.5633C>A p.P1878H | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.628); catalogued as rs750201908, COSV100944467; called by muse, mutect2, varscan2
- PRX | c.1801C>T p.P601S | Missense Mutation (SNP) | VAF 79/184 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99397644; called by muse, varscan2
- PRXL2A | c.373C>T p.Q125* | Nonsense Mutation (SNP) | VAF 36/51 reads (71%) | catalogued as rs1253835964, COSV100939783; called by muse, mutect2, varscan2
- PSG7 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 135/314 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101343227; called by muse, mutect2, varscan2
- PTPN21 | c.1439C>T p.S480L | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.273); catalogued as rs147095453; called by muse, mutect2, varscan2
- PTPRB | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51730945; called by muse, mutect2, varscan2
- PTPRD | c.5602G>A p.G1868R | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61963857, COSV61964189; called by muse, mutect2, varscan2
- PWWP3B | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs1204003233, COSV100531152; called by muse, mutect2, varscan2
- RAB3B | c.153del p.F51Lfs*11 | Frame Shift Del (DEL) | VAF 22/95 reads (23%) | catalogued as COSV63228388; called by mutect2, pindel, varscan2
- RAB3IP | c.485G>A p.R162Q (on ENST00000550536 / NM_175623.4; = p.R146Q on NM_022456.5) | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56084929; called by muse, mutect2, varscan2
- RADX | c.1253T>G p.V418G | Missense Mutation (SNP) | VAF 49/57 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100998821; called by muse, mutect2, varscan2
- RANBP3L | c.1120A>C p.T374P | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99683737; called by muse, mutect2, varscan2
- RASAL2 | c.2377C>T p.P793S | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.788); catalogued as COSV100862563; called by muse, mutect2, varscan2
- RASEF | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 51/100 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as rs769582859, COSV64586058, COSV64586726; called by muse, mutect2, varscan2
- RBM27 | c.2002C>T p.R668* | Nonsense Mutation (SNP) | VAF 48/123 reads (39%) | catalogued as rs1459327146, COSV99506032; called by muse, mutect2, varscan2
- RBM33 | c.2759C>T p.P920L | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV100265351; called by muse, mutect2
- RCAN2 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as COSV57818537; called by muse, mutect2, varscan2
- REG1A | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs200969301, COSV52069475; called by muse, mutect2, varscan2
- RERE | c.4238C>T p.P1413L | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs770280764, COSV61940407; called by muse, varscan2
- RHBDF1 | c.357G>T p.Q119H | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV99244523; called by muse, mutect2
- RIC3 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV58301736; called by muse, mutect2
- RIMS2 | c.1951G>A p.G651R (on ENST00000666250 / NM_001348490.2; = p.G459R on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51724044; called by muse, mutect2, varscan2
- RIPK1 | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99454308; called by muse, mutect2, varscan2
- RNASE6 | c.350G>A p.S117N | Missense Mutation (SNP) | VAF 64/139 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV100485917; called by muse, mutect2, varscan2
- RNF111 | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as rs1457455234, COSV100788944; called by muse, mutect2, varscan2
- RNF220 | c.146G>A p.G49D | Missense Mutation (SNP) | VAF 100/191 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100698506; called by muse, mutect2, varscan2
- RPH3AL | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs946208917, COSV100046744; called by muse, mutect2, varscan2
- RSF1 | c.2764C>T p.R922C | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771791885, COSV100407095; called by muse, mutect2, varscan2
- RSPO2 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 59/90 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as rs776068927, COSV52637198; called by muse, mutect2, varscan2
- RTL4 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 67/74 reads (91%) | SIFT tolerated (0.26); PolyPhen benign (0.05); catalogued as rs189407251, COSV61207672; called by muse, mutect2, varscan2
- RTP1 | c.240G>A p.W80* | Nonsense Mutation (SNP) | VAF 28/81 reads (35%) | catalogued as COSV56618164; called by muse, mutect2, varscan2
- RUBCN | c.2812C>T p.R938W | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761154086, COSV99583807; called by muse, mutect2, varscan2
- RUNX1T1 | c.445C>T p.R149C (on ENST00000265814 / NM_001198628.1; = p.R122C on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1354844348, COSV99751260; called by muse, mutect2, varscan2
- RXRB | c.1564C>T p.L522F | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs11970403, COSV100553803; called by muse, varscan2
- RYR2 | c.1393C>T p.P465S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.498); catalogued as COSV100769572; called by muse, mutect2, varscan2
- RYR2 | c.10484G>A p.R3495Q | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100769573, COSV63704214; called by muse, mutect2, varscan2
- RYR3 | c.6710G>A p.G2237E | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1402878006, COSV63109402, COSV63109651; called by muse, mutect2, varscan2
- RYR3 | c.7547A>T p.Y2516F (on ENST00000389232; = p.Y2517F on NM_001036.6) | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101212535; called by muse, mutect2, varscan2
- RYR3 | c.8161G>A p.D2721N (on ENST00000389232; = p.D2722N on NM_001036.6) | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs376553827; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAMD9 | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 109/387 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs755238026, COSV66075654; called by muse, mutect2, varscan2
- SCN1A | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 66/171 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.959); catalogued as rs769582667, COSV57660030; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN5A | c.1151C>T p.S384F | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100346860, COSV100347738; called by muse, mutect2, varscan2
- SCN7A | c.1113G>A p.M371I | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV101313172; called by muse, mutect2, varscan2
- SDCCAG8 | c.2089G>A p.E697K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.602); catalogued as COSV100285142; called by muse, mutect2, varscan2
- SEC31B | c.1049C>T p.S350F | Missense Mutation (SNP) | VAF 35/45 reads (78%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as rs761467322, COSV64824642; called by muse, mutect2, varscan2
- SEL1L3 | c.1651C>T p.L551F | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV99340038; called by muse, mutect2, varscan2
- SELE | c.1442G>A p.W481* | Nonsense Mutation (SNP) | VAF 64/145 reads (44%) | catalogued as COSV100324687; called by muse, mutect2, varscan2
- SELP | c.111A>T p.K37N | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.568); catalogued as COSV99739582; called by muse, mutect2, varscan2
- SEMG1 | c.305G>A p.G102E | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.993); catalogued as COSV99725201; called by muse, mutect2, varscan2
- SERPINA3 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101261673; called by muse, mutect2, varscan2
- SERPINA4 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.66); PolyPhen benign (0.072); catalogued as rs13306799, COSV54070092; called by muse, mutect2
- SERPINA5 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.147); catalogued as rs1289731471, COSV100291580; called by muse, mutect2, varscan2
- SERPIND1 | c.635G>A p.R212K | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.105); catalogued as COSV99300170; called by muse, mutect2, varscan2
- SERPINF1 | c.315C>A p.H105Q | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV99628792; called by muse, mutect2, varscan2
- SERPINF1 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs781059865, COSV99628795; called by muse, mutect2, varscan2
- SIGLEC7 | c.267G>T p.E89D | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as COSV99978641; called by muse, mutect2, varscan2
- SIM2 | c.912G>C p.W304C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99293129; called by muse, mutect2
- SIPA1L1 | c.2041G>A p.E681K | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62169895; called by muse, mutect2, varscan2
- SIRPB1 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 79/140 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99498333; called by muse, varscan2
- SLC13A4 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 32/216 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.075); catalogued as COSV100818845; called by muse, mutect2, varscan2
- SLC15A2 | c.1660G>A p.G554R | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.807); catalogued as rs1474568739, COSV55195482, COSV99815858; called by muse, mutect2, varscan2
- SLC17A6 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99581280; called by muse, mutect2, varscan2
- SLC17A6 | c.1229G>A p.G410E | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as COSV54133155; called by muse, mutect2, varscan2
- SLC22A2 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 45/55 reads (82%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs368105668, COSV100870994; called by muse, mutect2, varscan2
- SLC28A2 | c.665G>A p.G222E | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61663768; called by muse, mutect2, varscan2
- SLC35F3 | c.734C>T p.S245F (on ENST00000366617 / NM_001300845.1; = p.S314F on NM_173508.4) | Missense Mutation (SNP) | VAF 64/149 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100784773; called by muse, mutect2, varscan2
- SLC4A5 | c.2357C>T p.S786F | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1400184330, COSV61034191; called by muse, mutect2, varscan2
- SLC4A8 | c.3223G>A p.V1075I | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.146); catalogued as rs1247058821, COSV101493104; called by muse, mutect2, varscan2
- SLC5A1 | c.1799G>A p.G600E | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.613); catalogued as COSV56683831; called by muse, mutect2, varscan2
- SLC5A8 | c.1619G>A p.S540N | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73310893; called by muse, mutect2, varscan2
- SLC6A5 | c.1031C>T p.S344L | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs371937657; called by muse, mutect2, varscan2
- SLCO1B3 | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs767172087, COSV53946536; called by muse, mutect2, varscan2
- SLCO1B3 | c.487G>T p.V163L | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs754627543, COSV99681280, COSV99681695; called by muse, mutect2, varscan2
- SLCO5A1 | c.2099C>T p.P700L | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99479778; called by muse, mutect2, varscan2
- SLCO6A1 | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101134241; called by muse, mutect2, varscan2
- SLITRK1 | c.1291G>T p.D431Y | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV100999774, COSV65674410; called by muse, mutect2, varscan2
- SLITRK1 | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV65676878; called by muse, mutect2, varscan2
- SLITRK6 | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101233215; called by muse, mutect2, varscan2
- SMG6 | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 73/142 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as COSV99558048; called by muse, mutect2, varscan2
- SORL1 | c.4300G>A p.D1434N | Missense Mutation (SNP) | VAF 50/63 reads (79%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as COSV99493531; called by muse, mutect2, varscan2
- SORL1 | c.6148G>A p.E2050K | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.664); catalogued as COSV52750180; called by muse, mutect2, varscan2
- SPACA1 | c.752G>A p.W251* | Nonsense Mutation (SNP) | VAF 35/43 reads (81%) | catalogued as rs781552345, COSV99389402; called by muse, mutect2, varscan2
- SPAG17 | c.2836C>T p.R946* | Nonsense Mutation (SNP) | VAF 53/70 reads (76%) | catalogued as rs201253941, COSV60463148, COSV60465006; called by muse, mutect2, varscan2
- SPATA16 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs1350735686, COSV100651126; called by muse, mutect2, varscan2
- SPATS2 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as rs1463648348, COSV100423456; called by muse, mutect2, varscan2
- SPEM1 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs765723181, COSV100080968; called by muse, mutect2, varscan2
- SPG11 | c.2599C>T p.L867F | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99968444, COSV99969189; called by muse, mutect2, varscan2
- SPHKAP | c.2396G>A p.G799E | Missense Mutation (SNP) | VAF 77/185 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100764047; called by muse, mutect2, varscan2
- SPIDR | c.1331G>A p.W444* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as rs370648908; called by muse, mutect2, varscan2
- SPIDR | c.1332G>A p.W444* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as COSV99854820; called by muse, mutect2, varscan2
- SPRR2D | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 62/160 reads (39%) | SIFT tolerated, low confidence (0.44); PolyPhen possibly damaging (0.485); catalogued as rs747694219, COSV100836033; called by muse, mutect2, varscan2
- SRPK3 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 20/25 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV54206105; called by muse, mutect2, varscan2
- SRRM2 | c.6385C>T p.R2129C | Missense Mutation (SNP) | VAF 77/184 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs375690866; called by muse, mutect2, varscan2
- SRRT | c.2014C>T p.P672S | Missense Mutation (SNP) | VAF 84/174 reads (48%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); catalogued as COSV99573988; called by muse, mutect2, varscan2
- SSTR3 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as rs1429614547, COSV100142624; called by muse, mutect2, varscan2
- STEAP4 | c.1214G>A p.R405K | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs546856958, COSV100112522, COSV100112534; called by muse, mutect2, varscan2
- STMN4 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV56108746; called by muse, mutect2, varscan2
- SULT1C3 | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100227420; called by muse, mutect2, varscan2
- SUN1 | c.2392C>T p.R798W (on ENST00000405266 / NM_001367651.1; = p.R678W on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 200/438 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769875681, COSV99768544; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SUSD1 | c.593T>A p.L198Q | Missense Mutation (SNP) | VAF 61/162 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.876); catalogued as COSV100813257; called by muse, mutect2, varscan2
- SVEP1 | c.2188C>T p.P730S | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs1356467470, COSV100237786; called by muse, mutect2, varscan2
- SVEP1 | c.1978C>T p.Q660* | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as COSV57051056; called by muse, mutect2, varscan2
- SYNE1 | c.5113G>A p.E1705K (on ENST00000367255 / NM_182961.4; = p.E1712K on NM_033071.3) | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV54970041; called by muse, mutect2, varscan2
- SYNPO2 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100205403; called by muse, mutect2, varscan2
- TANC2 | c.5231C>T p.S1744F | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as rs767537932, COSV101267365; called by muse, mutect2, varscan2
- TAS1R2 | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.797); catalogued as COSV100946198; called by muse, mutect2, varscan2
- TAS2R3 | c.929C>G p.S310C | Missense Mutation (SNP) | VAF 79/182 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV99924505; called by muse, mutect2, varscan2
- TASP1 | c.157C>T p.H53Y | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs745546208, COSV100534545; called by muse, mutect2, varscan2
- TBX20 | c.1244C>T p.S415L | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.079); catalogued as rs111403731, COSV68786496; called by muse, varscan2
- TCHHL1 | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 65/132 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100916527, COSV64286354; called by muse, mutect2, varscan2
- TEX44 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.07); PolyPhen benign (0.278); catalogued as rs928628540, COSV100009707; called by muse, mutect2, varscan2
- THBS1 | c.1640C>T p.P547L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99527852; called by muse, mutect2, varscan2
- THSD7B | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs752809070, COSV55657303; called by muse, mutect2, varscan2
- TIMMDC1 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99809543; called by muse, mutect2, varscan2
- TLR8 | c.2386C>T p.P796S (on ENST00000218032 / NM_138636.5; = p.P814S on NM_016610.4) | Missense Mutation (SNP) | VAF 45/49 reads (92%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54319784, COSV54321204; called by muse, mutect2, varscan2
- TMC7 | c.2090G>T p.R697L | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV100432429, COSV58587546; called by muse, mutect2, varscan2
- TMEM132B | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 87/200 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.085); catalogued as COSV100169304; called by muse, mutect2, varscan2
- TMEM151A | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as rs566676531, COSV100516909; called by muse, varscan2
- TMPRSS15 | c.2719G>A p.G907R | Missense Mutation (SNP) | VAF 60/119 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs1568977885, COSV53049174, COSV99517618; called by muse, mutect2, varscan2
- TNN | c.169C>T p.Q57* | Nonsense Mutation (SNP) | VAF 28/47 reads (60%) | catalogued as COSV99511715; called by muse, mutect2, varscan2
- TNS3 | c.1708C>T p.P570S | Missense Mutation (SNP) | VAF 66/141 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.311); catalogued as rs1246020952, COSV100235402; called by muse, mutect2, varscan2
- TP63 | c.1974G>A p.W658* | Nonsense Mutation (SNP) | VAF 37/64 reads (58%) | catalogued as COSV99286604; called by muse, mutect2, varscan2
- TPH2 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 108/286 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); catalogued as COSV100422021; called by muse, mutect2, varscan2
- TPSB2 | c.802C>T p.H268Y | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs1272889171, COSV99326641; called by muse, mutect2, varscan2
- TRANK1 | c.6764C>T p.S2255F | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV57159818; called by muse, mutect2, varscan2
- TRERF1 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs759718746, COSV61669675; called by muse, mutect2, varscan2
- TRIM15 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as rs759168034, COSV64988982; called by muse, mutect2, varscan2
- TRIM46 | c.1514G>T p.R505L | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100583578, COSV100583760; called by muse, mutect2, varscan2
- TRIM69 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1288265306, COSV100274252; called by muse, mutect2, varscan2
- TRIOBP | c.1117C>T p.P373S | Missense Mutation (SNP) | VAF 59/112 reads (53%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV100730807, COSV60378850; called by muse, mutect2, varscan2
- TRIOBP | c.4486G>A p.E1496K | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.024); catalogued as COSV100730808; called by muse, mutect2, varscan2
- TRIOBP | c.6955G>A p.G2319R (on ENST00000644935 / NM_001039141.3; = p.G606R on NM_007032.5) | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100730809; called by muse, mutect2, varscan2
- TRPM7 | c.356T>G p.V119G | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV100539734; called by muse, mutect2, varscan2
- TTC29 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.834); catalogued as COSV100283607; called by muse, mutect2, varscan2
- TTC39B | c.1532C>T p.P511L | Missense Mutation (SNP) | VAF 45/55 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52614116, COSV99894844; called by muse, mutect2, varscan2
- TTLL7 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.014); catalogued as rs1331675085, COSV99552245; called by muse, mutect2, varscan2
- TTN | c.91978A>T p.R30660* (on ENST00000591111; = p.R23236* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 52/118 reads (44%) | catalogued as COSV100606605; called by muse, mutect2, varscan2
- TTN | c.74848G>A p.E24950K (on ENST00000591111; = p.E17526K on NM_003319.4) | Missense Mutation (SNP) | VAF 69/140 reads (49%) | PolyPhen probably damaging (0.994); catalogued as COSV100606608; called by muse, mutect2, varscan2
- TTN | c.16747G>A p.D5583N (on ENST00000591111; = p.D4656N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/115 reads (37%) | PolyPhen probably damaging (0.964); catalogued as COSV59875030; called by muse, mutect2, varscan2
- TTN | c.4712C>T p.S1571F (on ENST00000591111; = p.S1525F on NM_003319.4) | Missense Mutation (SNP) | VAF 26/67 reads (39%) | PolyPhen benign (0.003); catalogued as COSV60260972, COSV60410943; called by muse, mutect2, varscan2
- TTN | c.3616G>A p.A1206T (on ENST00000591111; = p.A1160T on NM_003319.4) | Missense Mutation (SNP) | VAF 19/47 reads (40%) | PolyPhen possibly damaging (0.844); catalogued as rs200749662, COSV100606635; called by muse, mutect2
- TTPAL | c.181C>T p.L61F | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99375411; called by muse, mutect2, varscan2
- TULP1 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV57693849; called by muse, mutect2, varscan2
- TXNDC2 | c.1483G>T p.V495L (on ENST00000306084 / NM_001098529.2; = p.V428L on NM_032243.6) | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV100046010; called by muse, mutect2, varscan2
- UBASH3B | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.438); catalogued as COSV99417461; called by muse, mutect2, varscan2
- UGT2A2 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs371537243; called by muse, mutect2, varscan2
- UGT2B28 | c.1465C>T p.H489Y | Missense Mutation (SNP) | VAF 66/157 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.533); catalogued as rs1201727499, COSV100158725, COSV100158991; called by muse, mutect2, varscan2
- USH2A | c.9355C>T p.R3119C | Missense Mutation (SNP) | VAF 80/142 reads (56%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.446); catalogued as rs576236830, COSV56335521; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USP3 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99165683; called by muse, mutect2, varscan2
- USP37 | c.851C>T p.T284I | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs1249186605, COSV99294300; called by muse, mutect2, varscan2
- VPS13A | c.7489C>T p.R2497C | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762732340, COSV62439620; called by muse, mutect2, varscan2
- VPS13C | c.7862T>A p.V2621D (on ENST00000644861 / NM_020821.3; = p.V2578D on NM_017684.5) | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.947); catalogued as COSV99828169; called by muse, mutect2, varscan2
- WDR36 | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); catalogued as rs1410152602, COSV101540789; called by muse, mutect2, varscan2
- WDR36 | c.2075C>T p.S692F | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); catalogued as rs1228468159, COSV72605360; called by muse, mutect2, varscan2
- WHRN | c.1193G>A p.G398E | Missense Mutation (SNP) | VAF 48/83 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as rs201612708, COSV99470137; called by muse, mutect2, varscan2
- WNT9B | c.703G>A p.G235S | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99255128; called by muse, mutect2, varscan2
- XIRP2 | c.553G>A p.V185I (on ENST00000628543; = p.V360I on NM_152381.6) | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.038); catalogued as COSV99741711; called by muse, mutect2, varscan2
- XIRP2 | c.8217A>T p.K2739N (on ENST00000628543; = p.K2914N on NM_152381.6) | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99741714; called by muse, mutect2, varscan2
- XIRP2 | c.9163C>T p.R3055C (on ENST00000628543; = p.R3230C on NM_152381.6) | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV54685665; called by muse, mutect2, varscan2
- XKR7 | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV101629249; called by muse, mutect2, varscan2
- YIPF1 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as rs1322586407, COSV50777916; called by muse, mutect2, varscan2
- YTHDC2 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.205); catalogued as COSV99363164; called by muse, mutect2, varscan2
- ZBTB10 | c.1300C>T p.Q434* | Nonsense Mutation (SNP) | VAF 26/52 reads (50%) | catalogued as COSV100990170; called by muse, mutect2, varscan2
- ZCCHC8 | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100288613; called by muse, mutect2, varscan2
- ZDBF2 | c.1687C>T p.R563W | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs771789452, COSV65621821; called by muse, mutect2, varscan2
- ZFHX4 | c.4616G>A p.R1539H | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs981659626, COSV50703705; called by muse, mutect2, varscan2
- ZFP91 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.809); catalogued as COSV100284447; called by muse, mutect2, varscan2
- ZFYVE1 | c.2284C>T p.H762Y | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.508); catalogued as COSV100606704; called by muse, mutect2, varscan2
- ZIC4 | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs1342760692, COSV67173763; called by muse, mutect2, varscan2
- ZKSCAN2 | c.1799C>T p.S600L | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1308038742, COSV100048030; called by muse, mutect2, varscan2
- ZMYM6 | c.1190C>T p.S397F | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1379104156, COSV100593126; called by muse, mutect2, varscan2
- ZNF233 | c.875G>A p.G292E | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV100492221; called by muse, mutect2, varscan2
- ZNF287 | c.1217G>A p.R406K | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0.011); catalogued as COSV101209371; called by muse, mutect2, varscan2
- ZNF334 | c.1648G>A p.G550R | Missense Mutation (SNP) | VAF 66/198 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100749059; called by muse, mutect2, varscan2
- ZNF335 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV100532894; called by muse, mutect2, varscan2
- ZNF407 | c.4243C>T p.R1415C | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs551880785, COSV55255546, COSV55256362; called by muse, mutect2, varscan2
- ZNF43 | c.1985C>T p.S662F | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT tolerated (0.67); PolyPhen benign (0.04); catalogued as COSV100731780; called by muse, mutect2, varscan2
- ZNF488 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT tolerated (0.27); PolyPhen benign (0.046); catalogued as rs536291384; called by muse, mutect2, varscan2
- ZNF516 | c.2533C>G p.P845A | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.192); catalogued as COSV101487258; called by muse, mutect2, varscan2
- ZNF536 | c.1966G>A p.D656N | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as COSV100835077; called by muse, mutect2, varscan2
- ZNF572 | c.1580C>T p.S527L | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV60002504, COSV60003085; called by muse, mutect2, varscan2
- ZNF583 | c.195G>T p.W65C | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99382068; called by muse, mutect2, varscan2
- ZNF599 | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.648); catalogued as rs1345356540, COSV100251093; called by muse, mutect2, varscan2
- ZNF611 | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 66/141 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs901901307, COSV100160215; called by muse, mutect2, varscan2
- ZNF667 | c.496C>T p.H166Y | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99410288; called by muse, mutect2, varscan2
- ZNF8 | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV99544243; called by muse, mutect2, varscan2
- ZNF804B | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV100303196; called by muse, mutect2, varscan2
- ZNF836 | c.550C>T p.L184F | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV59081911; called by muse, mutect2, varscan2
- FCGBP | c.7052C>T p.P2351L | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GAS2L2 | c.1966C>T p.Q656* | Nonsense Mutation (SNP) | VAF 47/71 reads (66%) | called by muse, mutect2, varscan2
- GNAL | c.1084del p.V362Cfs*44 (on ENST00000269162 / NM_001142339.3; = p.V439Cfs*44 on NM_182978.4) | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | called by mutect2, pindel, varscan2
- HNF1B | c.992C>T p.S331F | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- IGHV4-61 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 58/188 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- IGHV7-81 | c.278C>T p.T93I | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- PLG | c.156del p.K52Nfs*23 | Frame Shift Del (DEL) | VAF 70/87 reads (80%) | called by mutect2, pindel*, varscan2
- SLC22A13 | c.1465C>T p.P489S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); called by mutect2, varscan2
- TRAV34 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.51); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TRAV8-2 | c.104G>A p.G35E | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- VARS1 | c.249_255del p.L84Afs*22 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- VN1R5 | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, varscan2
- ABCA9 | c.4734C>T p.F1578= | Silent (SNP) | VAF 39/71 reads (55%) | catalogued as rs764557816, COSV100383003; called by muse, mutect2, varscan2
- ABCB5 | c.2178C>T p.T726= (on ENST00000404938 / NM_001163941.2; = p.T281= on NM_178559.6) | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as COSV99328126; called by muse, mutect2, varscan2
- ACACB | c.3969C>T p.F1323= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as COSV100622738; called by muse, mutect2, varscan2
- ACOXL | c.1317G>A p.V439= (on ENST00000389811 / NM_001371254.1; = p.V409= on NM_001142807.4) | Silent (SNP) | VAF 38/96 reads (40%) | catalogued as rs868698282, COSV101094708; called by muse, mutect2, varscan2
- ACTC1 | c.663C>T p.V221= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as rs766868624, COSV99291776; ClinVar: likely benign; called by muse, mutect2, varscan2
- ACTN4 | c.1911C>T p.L637= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as COSV99400069; called by muse, mutect2, varscan2
- ADGRG5 | c.1383C>T p.G461= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV100446388; called by muse, mutect2, varscan2
- AGBL1 | c.1620C>T p.P540= | Silent (SNP) | VAF 35/82 reads (43%) | catalogued as COSV66851108, COSV66878055; called by muse, mutect2, varscan2
- AHNAK | c.12558A>G p.L4186= | Silent (SNP) | VAF 75/276 reads (27%) | catalogued as rs1238065231, COSV57218320, COSV99946937; called by muse, mutect2, varscan2
- AK7 | c.2031A>G p.S677= | Silent (SNP) | VAF 31/60 reads (52%) | catalogued as COSV99967180; called by muse, mutect2, varscan2
- ANGEL2 | c.438G>A p.T146= | Silent (SNP) | VAF 48/91 reads (53%) | catalogued as rs749051875, COSV64737817; called by muse, mutect2, varscan2
- ANGPTL5 | c.708G>A p.Q236= | Silent (SNP) | VAF 23/30 reads (77%) | catalogued as COSV100527750; called by muse, mutect2, varscan2
- ANK1 | c.1917T>C p.L639= | Silent (SNP) | VAF 37/74 reads (50%) | catalogued as COSV99224857; called by muse, mutect2, varscan2
- AP2B1 | c.2433C>T p.I811= | Silent (SNP) | VAF 31/53 reads (58%) | catalogued as rs1555586251; called by muse, mutect2, varscan2
- AP3D1 | c.2304C>T p.I768= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as rs755724535, COSV61426414; called by muse, mutect2, varscan2
- APBB3 | c.1167C>T p.A389= (on ENST00000357560 / NM_133173.2; = p.A396= on NM_006051.3) | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV100021271; called by muse, mutect2, varscan2
- APOL1 | c.492G>A p.G164= | Silent (SNP) | VAF 44/124 reads (35%) | catalogued as COSV100045863; called by muse, mutect2, varscan2
- AQP10 | c.300C>T p.L100= | Silent (SNP) | VAF 52/131 reads (40%) | catalogued as rs140477648; called by muse, mutect2, varscan2
- ARHGAP22 | c.714C>T p.L238= | Silent (SNP) | VAF 10/13 reads (77%) | catalogued as COSV50952792, COSV99985021; called by muse, mutect2, varscan2
- ARHGAP45 | c.1692C>T p.S564= | Silent (SNP) | VAF 35/73 reads (48%) | catalogued as rs374604498; called by muse, mutect2, varscan2
- ASIC4 | c.429C>T p.P143= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV100761657; called by muse, mutect2, varscan2
- ATAD2B | c.1752C>T p.I584= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV99477485; called by muse, mutect2, varscan2
- ATF7IP | c.618T>C p.S206= | Silent (SNP) | VAF 53/133 reads (40%) | catalogued as COSV99661525; called by muse, mutect2, varscan2
- ATF7IP | c.2511C>T p.S837= | Silent (SNP) | VAF 51/114 reads (45%) | catalogued as rs1319426475, COSV99661529; called by muse, mutect2, varscan2
- ATF7IP2 | c.984G>A p.E328= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as rs1204606935, COSV100202584; called by muse, mutect2, varscan2
- ATP10D | c.3327G>A p.R1109= | Silent (SNP) | VAF 61/145 reads (42%) | catalogued as rs1390299056, COSV99905502; called by muse, mutect2, varscan2
- ATP6V0D1 | c.882C>T p.F294= | Silent (SNP) | VAF 64/133 reads (48%) | catalogued as COSV52097924, COSV99341104; called by muse, mutect2, varscan2
- ATP8A1 | c.480C>T p.T160= | Silent (SNP) | VAF 36/94 reads (38%) | catalogued as rs1208288079, COSV100045777; called by muse, mutect2, varscan2
- AVP | c.102C>T p.S34= | Silent (SNP) | VAF 51/152 reads (34%) | catalogued as rs3729964; called by muse, mutect2, varscan2
- BAG6 | c.339C>T p.S113= | Silent (SNP) | VAF 44/136 reads (32%) | catalogued as COSV99276868; called by muse, mutect2, varscan2
- BDNF | c.657C>T p.T219= | Silent (SNP) | VAF 41/116 reads (35%) | catalogued as COSV59235336; called by muse, mutect2, varscan2
- BRINP2 | c.1309C>T p.L437= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as COSV100838030; called by muse, mutect2, varscan2
- BTBD8 | c.771G>A p.L257= | Silent (SNP) | VAF 50/99 reads (51%) | catalogued as rs1471887889, COSV100730240; called by muse, mutect2, varscan2
- C1orf115 | c.420C>T p.F140= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as rs762749655, COSV54273872; called by muse, mutect2, varscan2
- C2CD2L | c.1765C>T p.L589= | Silent (SNP) | VAF 55/68 reads (81%) | catalogued as COSV100371165; called by muse, mutect2, varscan2
- C2orf78 | c.513C>T p.T171= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs867153162, COSV68519453; called by muse, mutect2, varscan2
- C5AR1 | c.672C>T p.F224= | Silent (SNP) | VAF 52/109 reads (48%) | catalogued as COSV61893324; called by muse, mutect2, varscan2
- CADPS2 | c.1077C>T p.S359= | Silent (SNP) | VAF 115/211 reads (55%) | catalogued as rs765072917, COSV57347268; ClinVar: likely benign; called by muse, mutect2, varscan2
- CARD9 | c.918G>A p.K306= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs1158158279, COSV100261144; called by muse, mutect2, varscan2
- CASR | c.2880T>A p.G960= (on ENST00000490131; = p.G1037= on NM_000388.4) | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV99948828; called by muse, mutect2, varscan2
- CAST | c.900C>T p.T300= (on ENST00000341926; = p.T383= on NM_001750.7 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV100352337; called by muse, mutect2, varscan2
- CATSPER1 | c.2013G>A p.V671= | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as COSV100375861; called by muse, mutect2, varscan2
- CCNF | c.1644C>T p.D548= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV99563508; called by muse, varscan2
- CD163 | c.3150C>T p.S1050= | Silent (SNP) | VAF 33/102 reads (32%) | catalogued as COSV63129509; called by muse, mutect2, varscan2
- CD163 | c.1581C>T p.I527= | Silent (SNP) | VAF 33/71 reads (46%) | catalogued as rs868301970, COSV100775801; called by muse, mutect2, varscan2
- CD5L | c.193C>T p.L65= | Silent (SNP) | VAF 83/176 reads (47%) | catalogued as COSV100941038; called by muse, mutect2, varscan2
- CDC6 | c.522C>T p.A174= | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as COSV99266554; called by muse, mutect2, varscan2
- CDH20 | c.1938G>A p.R646= | Silent (SNP) | VAF 58/116 reads (50%) | catalogued as rs763991374, COSV53017230; called by muse, mutect2, varscan2
- CDH6 | c.1872G>A p.V624= | Silent (SNP) | VAF 41/87 reads (47%) | catalogued as COSV54064350; called by muse, mutect2, varscan2
- CDSN | c.1482C>T p.I494= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV52537476, COSV99456815; called by muse, mutect2, varscan2
- CECR2 | c.2787C>T p.H929= (on ENST00000342247 / NM_001290047.2; = p.H746= on NM_001290046.1) | Silent (SNP) | VAF 58/120 reads (48%) | catalogued as rs749059089, COSV99377704; called by muse, mutect2, varscan2
- CES3 | c.402G>A p.E134= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV100309898; called by muse, mutect2, varscan2
- CFHR3 | c.972G>A p.V324= | Silent (SNP) | VAF 47/53 reads (89%) | catalogued as rs561946108, COSV100807517; called by muse, mutect2, varscan2
- CGN | c.2913C>G p.V971= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs1235870173, COSV54973130, COSV99641844, COSV99642203; called by muse, mutect2, varscan2
- CHI3L1 | c.795C>T p.F265= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as rs1440649388, COSV99703911; called by muse, mutect2, varscan2
- CHRM2 | c.348C>T p.I116= | Silent (SNP) | VAF 51/230 reads (22%) | catalogued as COSV57784326; called by muse, mutect2, varscan2
- CHRNA2 | c.633C>T p.I211= | Silent (SNP) | VAF 27/41 reads (66%) | catalogued as COSV99532150; called by muse, mutect2, varscan2
- CIITA | c.1380G>A p.G460= | Silent (SNP) | VAF 45/109 reads (41%) | catalogued as COSV100161781; called by muse, mutect2, varscan2
- CLCN4 | c.1647C>T p.I549= | Silent (SNP) | VAF 50/56 reads (89%) | catalogued as rs139942006, COSV66469294; called by muse, mutect2, varscan2
- CLRN2 | c.477G>A p.V159= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs374245458; called by muse, mutect2, varscan2
- CLSPN | c.3933C>T p.F1311= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV99230712; called by muse, mutect2, varscan2
- CMKLR1 | c.564C>T p.S188= (on ENST00000312143 / NM_001142344.2; = p.S186= on NM_004072.3) | Silent (SNP) | VAF 29/50 reads (58%) | catalogued as rs983476632, COSV100379331; called by muse, mutect2, varscan2
- CNGA1 | c.1545C>T p.I515= | Silent (SNP) | VAF 47/103 reads (46%) | catalogued as COSV100652202; called by muse, mutect2, varscan2
- COLEC12 | c.18A>T p.A6= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as COSV101232041, COSV101232118; called by muse, mutect2, varscan2
- CPA6 | c.963C>T p.L321= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV99913380; called by muse, mutect2, varscan2
- CPO | c.376C>T p.L126= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV99786453; called by muse, mutect2
- CRB1 | c.1707C>T p.F569= | Silent (SNP) | VAF 109/183 reads (60%) | catalogued as rs201885772, COSV66329457; called by muse, mutect2, varscan2
- CRNN | c.1236A>G p.S412= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as rs1557914635, COSV99664096; called by muse, mutect2, varscan2
- CSAG3 | c.318C>T p.F106= | Silent (SNP) | VAF 44/126 reads (35%) | catalogued as rs1232784999; called by muse, mutect2, varscan2
- CSPG4 | c.5775C>T p.A1925= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as rs772229061, COSV100413704; called by muse, mutect2, varscan2
- CTNNA2 | c.1263C>T p.F421= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as COSV100560112; called by muse, mutect2, varscan2
- CTNNA3 | c.1347C>T p.A449= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as COSV65555771; called by muse, mutect2, varscan2
- CTNNBL1 | c.1644C>T p.F548= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as rs866928928, COSV63744547; called by muse, mutect2, varscan2
- CYB561D1 | c.444C>T p.L148= | Silent (SNP) | VAF 38/72 reads (53%) | catalogued as COSV100149801; called by muse, mutect2, varscan2
- CYP2C19 | c.1461C>T p.F487= | Silent (SNP) | VAF 44/54 reads (81%) | catalogued as rs1199869109, COSV64907089; called by muse, mutect2, varscan2
- CYP4A11 | c.1423C>T p.L475= | Silent (SNP) | VAF 40/77 reads (52%) | catalogued as COSV100152318; called by muse, mutect2, varscan2
- CYP4A11 | c.1026G>A p.K342= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as rs1488137029, COSV100152321; called by muse, mutect2, varscan2
- DAG1 | c.2157C>T p.I719= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as COSV100444872; called by muse, mutect2, varscan2
- DCAF1 | c.3240C>T p.F1080= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs1553631463, COSV60042920; called by muse, mutect2
- DDX54 | c.1590C>T p.S530= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV100013804; called by muse, mutect2, varscan2
- DEF8 | c.345C>T p.F115= (on ENST00000268676 / NM_207514.3; = p.F54= on NM_017702.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as rs267604684, COSV51918478; called by muse, mutect2, varscan2
- DGKA | c.2052G>A p.E684= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as COSV100092965; called by muse, mutect2, varscan2
- DISP3 | c.3729C>T p.I1243= | Silent (SNP) | VAF 25/44 reads (57%) | catalogued as COSV99608273; called by muse, mutect2, varscan2
- DNAH3 | c.6987G>A p.K2329= | Silent (SNP) | VAF 57/121 reads (47%) | catalogued as rs765263590, COSV99766647; called by muse, mutect2, varscan2
- DNAH3 | c.4942C>T p.L1648= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV99766652; called by muse, mutect2, varscan2
- DNAH5 | c.12624C>T p.I4208= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as COSV54235863, COSV54255728; called by muse, mutect2, varscan2
- DNAH5 | c.7296C>T p.F2432= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as rs748328316, COSV54233897; called by muse, mutect2, varscan2
- DNAH8 | c.13284G>A p.Q4428= | Silent (SNP) | VAF 40/101 reads (40%) | catalogued as COSV100544525; called by muse, mutect2, varscan2
- DNMT3A | c.174C>T p.P58= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs762532386, COSV99261704; called by muse, mutect2
- DOCK10 | c.4275C>T p.H1425= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs1319301353, COSV99288976; called by muse, mutect2, varscan2
- DOCK8 | c.5298G>A p.R1766= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as rs1165725101, COSV101209897; called by muse, mutect2, varscan2
- DSC3 | c.456C>T p.F152= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as COSV64574280; called by muse, mutect2, varscan2
- DUS3L | c.1260C>T p.I420= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs755431326, COSV57831272; called by muse, mutect2, varscan2
- DUSP10 | c.456C>T p.P152= | Silent (SNP) | VAF 27/54 reads (50%) | catalogued as COSV100100351; called by muse, mutect2, varscan2
- DYTN | c.741C>T p.L247= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV101510822, COSV71751870; called by muse, mutect2, varscan2
- ELFN2 | c.1608C>T p.T536= | Silent (SNP) | VAF 47/108 reads (44%) | catalogued as COSV101297530; called by muse, mutect2, varscan2
- ELMO1 | c.486C>T p.F162= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as rs147249735; called by muse, mutect2, varscan2
301 further variants in this file (0 protein-altering or splice-affecting, 276 silent, 25 other) are not listed here.
